Somatic mutation profile of tumor specimen TCGA-UZ-A9PR-01A (aliquot TCGA-UZ-A9PR-01A-11D-A42J-10) from TCGA case TCGA-UZ-A9PR, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9PR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddb58e4e-4f70-4a36-914e-c4968c5713b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PR-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PR-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78dfc1eb-1375-4c88-88cc-ae4bcd0c0b72

The open-access MAF lists 112 somatic variants for this specimen: 90 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 21, Frame Shift Del 9, Nonsense Mutation 3, In Frame Del 2, Splice Region 1, Splice Site 1, Frame Shift Ins 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.4290C>G p.F1430L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100588866; called by muse, mutect2, varscan2
- ACACB | c.5673C>A p.Y1891* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100623126; called by muse, mutect2, varscan2
- ADAM2 | c.151A>T p.I51F | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55861624, COSV99697691; called by muse, mutect2, varscan2
- ADAMTS8 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99961326; called by muse, mutect2, varscan2
- AKAP13 | c.2014G>T p.V672L | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV100774252; called by muse, mutect2, varscan2
- ALKBH2 | c.509A>T p.E170V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99980506; called by muse, mutect2, varscan2
- APMAP | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs905609748, COSV99468885; called by muse, mutect2, varscan2
- ARHGEF25 | c.1220T>C p.V407A | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.509); catalogued as rs1313264484, COSV99678172; called by muse, mutect2, varscan2
- ARID1B | c.3025T>C p.S1009P | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV99270910; called by muse, mutect2, varscan2
- ATAD3B | c.*400C>T | Splice Region (SNP) | VAF 39/105 reads (37%) | catalogued as COSV100426562; called by muse, mutect2, varscan2
- ATP13A4 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs763560145, COSV55068649; called by muse, mutect2, varscan2
- AUP1 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as rs377142567; called by muse, mutect2, varscan2
- BAHCC1 | c.1122C>A p.D374E | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.124); catalogued as rs371913800, COSV100311923; called by muse, mutect2, varscan2
- C8orf37 | c.515A>T p.K172M | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV54412618; called by muse, mutect2, varscan2
- CACNA2D4 | c.890A>C p.D297A | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99766176; called by muse, mutect2, varscan2
- CADPS | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV99339947; called by muse, mutect2, varscan2
- CCT3 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99827432; called by muse, mutect2, varscan2
- CHD7 | c.8971G>A p.E2991K | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV101418360; called by muse, mutect2, varscan2
- CLCNKB | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100990389; called by muse, mutect2, varscan2
- CLUH | c.2570C>T p.A857V (on ENST00000435359; = p.A896V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV101425831; called by muse, mutect2, varscan2
- DDX43 | c.1740A>C p.R580S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100944037; called by muse, mutect2, varscan2
- DIP2A | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100596200; called by muse, mutect2, varscan2
- DRICH1 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100497482; called by muse, varscan2
- EFHC2 | c.2174T>A p.M725K | Missense Mutation (SNP) | VAF 138/151 reads (91%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV100638010; called by muse, mutect2, varscan2
- EMILIN1 | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99566433; called by muse, mutect2, varscan2
- ERLEC1 | c.1102-1G>C p.X368_splice | Splice Site (SNP) | VAF 50/125 reads (40%) | catalogued as COSV99483149; called by muse, mutect2, varscan2
- FANCM | c.4546G>A p.A1516T | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1321105063, COSV99951410; called by muse, mutect2, varscan2
- FGFBP3 | c.754T>G p.F252V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100284650; called by muse, mutect2, varscan2
- FUBP1 | c.1475G>C p.G492A | Missense Mutation (SNP) | VAF 99/236 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as COSV99629288; called by muse, mutect2, varscan2
- GART | c.734A>T p.D245V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.298); catalogued as COSV100738234; called by muse, mutect2, varscan2
- GART | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.215); catalogued as COSV63114005; called by muse, mutect2, varscan2
- HDHD2 | c.684T>G p.Y228* | Nonsense Mutation (SNP) | VAF 40/81 reads (49%) | catalogued as COSV100321373; called by muse, mutect2, varscan2
- IBTK | c.146A>G p.D49G | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100091183; called by muse, mutect2, varscan2
- ITPR1 | c.6443C>T p.S2148F (on ENST00000354582; = p.S2093F on NM_002222.7) | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100232505; called by muse, mutect2, varscan2
- LAMA3 | c.9151G>A p.D3051N (on ENST00000313654 / NM_198129.4; = p.D1442N on NM_000227.6) | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99335500; called by muse, mutect2, varscan2
- LPCAT1 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV99359223; called by muse, mutect2, varscan2
- LTB4R2 | c.1130G>A p.G377E (on ENST00000528054; = p.G346E on NM_019839.5) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV51867403, COSV99351022; called by muse, mutect2, varscan2
- MYO9A | c.5339C>T p.S1780L | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100614006; called by muse, mutect2, varscan2
- MYSM1 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101524145; called by muse, mutect2, varscan2
- NLRP1 | c.1275G>C p.E425D | Missense Mutation (SNP) | VAF 75/129 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); catalogued as COSV99335013; called by muse, mutect2, varscan2
- NOS2 | c.1948G>C p.A650P | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569807, COSV58222947; called by muse, mutect2, varscan2
- NPR2 | c.2188G>C p.D730H | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV100439011; called by muse, mutect2, varscan2
- NPTX2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as rs769298573, COSV55716138; called by muse, mutect2, varscan2
- OR4K2 | c.817G>C p.V273L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV100064649; called by muse, mutect2, varscan2
- PAX5 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100814461; called by muse, mutect2, varscan2
- PCNX1 | c.5597T>A p.F1866Y | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99456618; called by muse, mutect2, varscan2
- PEX12 | c.827T>C p.L276S | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs1249994630, COSV99862191; called by muse, mutect2, varscan2
- PI4KA | c.1902G>T p.M634I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV99747649; called by muse, mutect2, varscan2
- POLR1A | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV99808153; called by muse, mutect2, varscan2
- POP1 | c.2326G>T p.G776W | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100856024; called by muse, mutect2, varscan2
- PPP1R15B | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100916364; called by muse, mutect2, varscan2
- PRSS55 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs200907557, COSV100153854; called by muse, mutect2, varscan2
- PTPRG | c.4291A>T p.I1431F | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV99876280; called by muse, mutect2, varscan2
- RABGAP1L | c.1270T>C p.W424R | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99272753; called by muse, mutect2, varscan2
- RDH12 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.074); catalogued as COSV99961901; called by muse, mutect2, varscan2
- RDH16 | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV100660155; called by muse, mutect2
- RP2 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as CM064191, COSV99509240; called by muse, mutect2
- SEC24C | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759109486, COSV100227059; called by muse, mutect2, varscan2
- SH3TC2 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100102162; called by muse, mutect2, varscan2
- SIGLEC11 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs768999708, COSV101389515; called by muse, mutect2, varscan2
- SLAMF6 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 111/258 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as rs148686177; called by muse, mutect2, varscan2
- SLC24A5 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99981936; called by muse, mutect2, varscan2
- SS18L1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100065174; called by muse, mutect2, varscan2
- SUV39H1 | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 71/76 reads (93%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV61920283; called by muse, mutect2, varscan2
- SYNE1 | c.23219C>T p.A7740V (on ENST00000367255 / NM_182961.4; = p.A7669V on NM_033071.3) | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99573462; called by muse, mutect2, varscan2
- TNN | c.3451A>T p.T1151S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99512586; called by muse, mutect2, varscan2
- TNPO3 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 88/383 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.175); catalogued as COSV99603276; called by muse, mutect2, varscan2
- TSKS | c.1653C>A p.H551Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as COSV55879857, COSV99883537; called by muse, mutect2, varscan2
- UBFD1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99563410; called by muse, varscan2
- UHRF1BP1L | c.2301G>C p.K767N | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99691940; called by muse, mutect2, varscan2
- UPP1 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100080829; called by muse, mutect2, varscan2
- USP20 | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV100204581, COSV59610829; called by muse, mutect2, varscan2
- VCP | c.400T>A p.Y134N | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100734295; called by muse, mutect2, varscan2
- XPO6 | c.1141G>T p.V381F | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100485234; called by muse, mutect2, varscan2
- ZBED9 | c.3785A>G p.E1262G | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101509345; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1585A>G p.K529E | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100048434; called by muse, mutect2, varscan2
- ADGRL3 | c.843_844del p.Y282* (on ENST00000506720 / NM_001322402.2; = p.Y214* on NM_015236.6) | Frame Shift Del (DEL) | VAF 40/90 reads (44%) | called by pindel, varscan2
- BNIP5 | c.318delinsTT p.V108Rfs*6 | Frame Shift Ins (INS) | VAF 19/57 reads (33%) | called by pindel, varscan2*
- CP | c.332del p.N111Tfs*14 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | called by mutect2, pindel, varscan2
- CYP2W1 | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EPPIN-WFDC6 | c.528_543del p.S176Rfs*24 | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | called by mutect2, pindel, varscan2
- KDM5A | c.2752_2755del p.T918Wfs*4 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- KRT13 | c.763del p.V255Sfs*16 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by mutect2, pindel, varscan2
- LIMCH1 | c.780_781del p.K261Ifs*6 | Frame Shift Del (DEL) | VAF 46/119 reads (39%) | called by mutect2, pindel, varscan2
- N4BP2 | c.2407del p.R803Gfs*25 | Frame Shift Del (DEL) | VAF 68/196 reads (35%) | called by mutect2, pindel, varscan2
- NR2F1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCG1 | c.1820_1821del p.H607Lfs*23 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel
- SNRK | c.1333del p.V445Wfs*29 | Frame Shift Del (DEL) | VAF 39/89 reads (44%) | called by mutect2, pindel, varscan2
- TBC1D22A | c.786_797del p.E262_Y265del | In Frame Del (DEL) | VAF 39/166 reads (23%) | called by mutect2, pindel, varscan2
- TIGD6 | c.147_149del p.K49_D50delinsN | In Frame Del (DEL) | VAF 29/86 reads (34%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.1320G>A p.Q440= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100030089; called by muse, mutect2, varscan2
- AMDHD1 | c.600T>C p.A200= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as COSV99900440; called by muse, mutect2, varscan2
- COL6A2 | c.1191C>T p.G397= | Silent (SNP) | VAF 87/268 reads (32%) | catalogued as COSV100153985; called by muse, mutect2
- DDX24 | c.786T>C p.N262= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV100428072; called by muse, mutect2, varscan2
- DOCK5 | c.1512C>T p.V504= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99377404; called by muse, mutect2, varscan2
- DRG1 | c.454C>T p.L152= | Silent (SNP) | VAF 50/97 reads (52%) | catalogued as COSV100513737, COSV58920233; called by muse, mutect2, varscan2
- HTR2A | c.1410T>C p.C470= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs780723077, COSV101096777; called by muse, mutect2, varscan2
- IQGAP1 | c.2652G>A p.Q884= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as COSV99185222; called by muse, mutect2, varscan2
- IRAG1 | c.1248A>C p.A416= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV101351479, COSV70212282; called by muse, mutect2, varscan2
- KMT2D | c.10602A>C p.V3534= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV99984445; called by muse, mutect2, varscan2
- MED13 | c.4296A>T p.A1432= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV101181170, COSV101181223; called by muse, mutect2, varscan2
- PLCB1 | c.420C>T p.N140= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as rs773275774, COSV100571781; called by muse, mutect2, varscan2
- PRRG4 | c.252G>A p.V84= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV99141418; called by muse, mutect2, varscan2
- QRICH1 | c.15A>G p.L5= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV100676923; called by muse, mutect2, varscan2
- RP1L1 | c.2916A>G p.T972= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as COSV101223469; called by muse, mutect2, varscan2
- SLC20A2 | c.1887C>A p.T629= | Silent (SNP) | VAF 71/150 reads (47%) | catalogued as rs754116669, COSV100646156; called by muse, mutect2, varscan2
- SLC4A4 | c.2880T>C p.C960= (on ENST00000264485 / NM_001098484.3; = p.C916= on NM_003759.4) | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV99141023; called by muse, mutect2, varscan2
- SMPDL3A | c.610A>C p.R204= | Silent (SNP) | VAF 47/134 reads (35%) | catalogued as COSV100868721; called by muse, mutect2, varscan2
- TMBIM6 | c.184T>C p.L62= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV99920810; called by muse, mutect2, varscan2
- TNN | c.2514C>T p.T838= | Silent (SNP) | VAF 132/305 reads (43%) | catalogued as rs1214727265, COSV99511599; called by muse, mutect2, varscan2
- ZNF609 | c.3813C>T p.S1271= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV100441508; called by muse, mutect2, varscan2
- C11orf40 | n.23T>C | RNA (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100296498; called by muse, mutect2, varscan2
